Somatic mutation profile of tumor specimen TCGA-FS-A1ZD-06A (aliquot TCGA-FS-A1ZD-06A-11D-A197-08) from TCGA case TCGA-FS-A1ZD, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 67.7 years (24,722 days).
Specimen TCGA-FS-A1ZD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67642baf-d97b-439d-a480-8289cfe60019.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZD-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZD-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0108530b-fc55-4179-9f95-9529f5cb441c

The open-access MAF lists 297 somatic variants for this specimen: 201 protein-altering or splice-affecting, 86 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 187, Silent 86, Nonsense Mutation 5, Intron 5, Splice Site 4, Splice Region 3, 3'UTR 2, RNA 2, Frame Shift Del 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/77 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PTEN | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 57/67 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1064793243, CM074466, COSV64295981, COSV64296046, COSV64296414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACD | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.569); catalogued as COSV54667378; called by muse, mutect2, varscan2
- ACTRT1 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 46/54 reads (85%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs373083231, COSV64419048; called by muse, mutect2, varscan2
- ADAM7 | c.1837G>A p.G613R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as COSV51539239; called by muse, mutect2, varscan2
- ADCY8 | c.2465C>T p.S822F | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs371754667, COSV53910739; called by muse, mutect2, varscan2
- AFF1 | c.2849C>T p.S950F | Missense Mutation (SNP) | VAF 96/149 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV57119387; called by muse, mutect2, varscan2
- AGA | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV52806148; called by muse, mutect2, varscan2
- AGO4 | c.2215G>A p.D739N | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs942311683, COSV64617065; called by muse, mutect2, varscan2
- AHNAK | c.1302G>A p.M434I | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as COSV57205564, COSV57212149; called by muse, mutect2, varscan2
- ALDH3B1 | c.1008C>G p.F336L | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV50288441, COSV50288522; called by muse, varscan2
- ALG1 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs992880561, COSV52157476; called by muse, mutect2, varscan2
- ALKBH2 | c.401G>A p.W134* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as COSV57449039; called by muse, mutect2, varscan2
- ANO4 | c.2708C>T p.S903L (on ENST00000392977 / NM_001286615.2; = p.S868L on NM_178826.4) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV54587306; called by muse, mutect2, varscan2
- APOBEC3D | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as COSV53326451; called by muse, mutect2, varscan2
- ARHGAP25 | c.1207G>C p.D403H (on ENST00000409202 / NM_001007231.3; = p.D395H on NM_014882.3) | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs1315038079, COSV54901830, COSV99771487; called by muse, mutect2, varscan2
- BDKRB1 | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as rs545558186, COSV53706065; called by muse, mutect2, varscan2
- C16orf78 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs146139981, COSV54559399; called by muse, varscan2
- C5orf24 | c.164G>A p.R55K | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.013); catalogued as COSV57542786; called by muse, mutect2, varscan2
- CACNA1B | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53124378; called by muse, mutect2
- CACNA1C | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); catalogued as rs786205744, COSV59713797; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CADM4 | c.265A>T p.I89F | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55928715; called by muse, mutect2, varscan2
- CCDC85B | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV57027916; called by mutect2, varscan2
- CD109 | c.2153C>T p.T718I | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54657332; called by muse, mutect2, varscan2
- CEP63 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV59676072; called by muse, mutect2
- CHL1 | c.3525C>A p.F1175L (on ENST00000397491 / NM_001253387.1; = p.F1191L on NM_006614.4) | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56592391; called by muse, mutect2, varscan2
- CHRNB4 | c.579T>G p.D193E | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as COSV55715904; called by muse, mutect2, varscan2
- CHST11 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.41); PolyPhen benign (0.076); catalogued as rs749545581, COSV57987056; called by muse, mutect2, varscan2
- CLCN3 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61626950; called by muse, mutect2, varscan2
- CLRN1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as rs199971192, COSV58993953; called by muse, mutect2, varscan2
- CMTM5 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.011); catalogued as rs778236991, COSV59305674; called by muse, mutect2, varscan2
- CNDP1 | c.1110A>G p.I370M | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs759249343, COSV62593840; called by muse, mutect2, varscan2
- COG6 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV62995810; called by muse, mutect2, varscan2
- CPT1C | c.1009C>T p.H337Y | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV54918969; called by muse, mutect2, varscan2
- CR2 | c.2476C>T p.R826C | Missense Mutation (SNP) | VAF 78/97 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as rs199700397, COSV65506135; called by muse, mutect2, varscan2
- CSNK1E | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); catalogued as COSV63290729; called by muse, mutect2, varscan2
- CTTNBP2 | c.2090C>T p.P697L | Missense Mutation (SNP) | VAF 95/100 reads (95%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV50389350; called by muse, mutect2, varscan2
- CUBN | c.6496T>G p.L2166V | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as COSV64714719; called by muse, mutect2, varscan2
- CWF19L2 | c.1782T>G p.D594E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56511950; called by muse, mutect2, varscan2
- CYLC1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT tolerated (0.83); PolyPhen benign (0.062); catalogued as COSV61411752; called by muse, mutect2, varscan2
- DERA | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1194097129, COSV70774142; called by muse, mutect2, varscan2
- DHX57 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as rs1231718000, COSV54884842; called by muse, mutect2, varscan2
- DLGAP2 | c.1637C>T p.S546F | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70097643; called by muse, mutect2, varscan2
- DNAH3 | c.2825C>T p.P942L | Missense Mutation (SNP) | VAF 73/250 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54519125; called by muse, mutect2, varscan2
- DNAH5 | c.9706G>A p.D3236N | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs374206128, COSV99451113; called by muse, mutect2, varscan2
- DNAH5 | c.8930C>T p.S2977F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV54219085; called by muse, mutect2, varscan2
- EFL1 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs993776666, COSV51605132, COSV99187231; called by muse, mutect2, varscan2
- EIF2AK4 | c.2936C>T p.S979F | Missense Mutation (SNP) | VAF 102/252 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as rs776612590, COSV55467978, COSV55471912; called by muse, mutect2, varscan2
- ELFN2 | c.2138C>T p.P713L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68744451; called by muse, mutect2
- EML5 | c.3257C>T p.S1086L | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV61345132; called by muse, mutect2, varscan2
- ESF1 | c.2396G>A p.R799Q | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371665082, COSV52521513; called by muse, mutect2, varscan2
- ETFB | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58535027, COSV58535930; called by muse, mutect2, varscan2
- FARSB | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56049438; called by muse, mutect2, varscan2
- FAT3 | c.12289G>A p.E4097K | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs1259865436, COSV53105095; called by muse, mutect2, varscan2
- FLVCR1 | c.695A>C p.K232T | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV63134144; called by muse, mutect2, varscan2
- FMO5 | c.1280C>T p.T427I | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.275); catalogued as COSV54206128; called by muse, mutect2, varscan2
- GJB6 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs1014466160, COSV53832477; called by muse, mutect2, varscan2
- GK2 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62626701; called by muse, mutect2, varscan2
- GLT6D1 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV65627650; called by muse, mutect2, varscan2
- GNL3 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV56477437; called by muse, mutect2, varscan2
- GPR182 | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs530506452, COSV55626104; called by muse, mutect2, varscan2
- GPRIN3 | c.2207C>T p.S736F | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs866357805, COSV60884211, COSV60884935; called by muse, mutect2, varscan2
- GRK7 | c.373T>G p.F125V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.927); catalogued as COSV53822597; called by muse, mutect2, varscan2
- GRTP1 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58149852; called by muse, mutect2, varscan2
- GYPE | c.152A>G p.N51S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV62262015; called by muse, varscan2
- HAO2 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as rs770798512, COSV58038841, COSV58039242; called by muse, mutect2, varscan2
- HERC2 | c.13189-1G>A p.X4397_splice | Splice Site (SNP) | VAF 28/54 reads (52%) | catalogued as COSV55321531; called by muse, mutect2, varscan2
- HIPK1 | c.-2G>T | Splice Region (SNP) | VAF 32/135 reads (24%) | catalogued as COSV65784399; called by muse, mutect2, varscan2
- HK3 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 62/101 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs774062628, COSV52839562; called by muse, mutect2, varscan2
- HNF4G | c.504G>A p.Q168= (on ENST00000354370 / NM_001330561.2; = p.Q215= on NM_004133.5) | Splice Region (SNP) | VAF 37/96 reads (39%) | catalogued as COSV62967909; called by muse, mutect2, varscan2
- IGSF9B | c.3076C>T p.P1026S | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.992); catalogued as rs772880801, COSV58067039; called by muse, mutect2, varscan2
- ISCA2 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53143282; called by muse, mutect2, varscan2
- ISLR2 | c.1409A>G p.N470S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.233); catalogued as COSV62302069; called by muse, mutect2, varscan2
- KCNJ16 | c.190A>C p.T64P | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52252800; called by muse, mutect2, varscan2
- KCNQ3 | c.2445T>A p.D815E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV66469748; called by muse, varscan2
- KDM3A | c.3020T>C p.V1007A | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57220721; called by muse, mutect2, varscan2
- KIAA1549 | c.4643C>T p.P1548L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1360936835, COSV54312776; called by muse, mutect2, varscan2
- KNDC1 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV58836164; called by muse, mutect2, varscan2
- L1TD1 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 90/178 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV63133455; called by muse, mutect2, varscan2
- LRPPRC | c.669G>A p.M223I | Missense Mutation (SNP) | VAF 156/390 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53237799; called by muse, mutect2, varscan2
- LRRC1 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63823672; called by muse, mutect2, varscan2
- LZTFL1 | c.84A>T p.R28S | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.109); catalogued as COSV56111337; called by muse, mutect2, varscan2
- MACF1 | c.13110+2T>C p.X4370_splice (on ENST00000372915; = p.X2303_splice on NM_012090.5) | Splice Site (SNP) | VAF 10/17 reads (59%) | catalogued as COSV57119173; called by muse, mutect2
- MAGEC1 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 111/121 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as COSV53571994; called by muse, mutect2, varscan2
- MECOM | c.922C>T p.P308S (on ENST00000468789 / NM_001105078.4; = p.P496S on NM_004991.4) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV52959050; called by muse, mutect2, varscan2
- MEP1A | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761106440, COSV57919753; called by muse, mutect2, varscan2
- MIER3 | c.1144C>T p.P382S (on ENST00000381199 / NM_001297599.2; = p.P381S on NM_152622.4) | Missense Mutation (SNP) | VAF 71/109 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV67082788, COSV67082941; called by muse, mutect2, varscan2
- MME | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV64707175; called by muse, mutect2, varscan2
- MOCOS | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54343016; called by muse, mutect2
- MYBPC2 | c.2248G>A p.D750N | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV63095134; called by muse, mutect2, varscan2
- MYH7B | c.2926G>A p.D976N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53419496; called by mutect2, varscan2
- MYH8 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 27/41 reads (66%) | catalogued as rs143063345, COSV67964249; called by muse, mutect2, varscan2
- MYH9 | c.2427G>A p.M809I | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1270895418, COSV53385563; called by mutect2, varscan2
- NCKAP5 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1324332097, COSV58441205; called by muse, mutect2, varscan2
- NDST3 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 48/128 reads (38%) | catalogued as COSV56618051; called by muse, mutect2, varscan2
- NEB | c.7069T>A p.F2357I | Missense Mutation (SNP) | VAF 205/459 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.273); catalogued as COSV51246106; called by muse, mutect2, varscan2
- NEB | c.4526G>A p.G1509E | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as COSV51253720; called by muse, mutect2
- NET1 | c.392C>T p.S131F (on ENST00000355029 / NM_001047160.3; = p.S77F on NM_005863.5) | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV61791377; called by muse, mutect2, varscan2
- NEU2 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV52092607; called by mutect2, varscan2
- NEXMIF | c.1924C>A p.P642T | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV50029267; called by muse, mutect2, varscan2
- NFIB | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs1342681852, COSV66626290; called by muse, mutect2, varscan2
- NIBAN2 | c.2168T>A p.V723E | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV55939832, COSV55941107; called by muse, mutect2, varscan2
- NKD2 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV56891440; called by muse, mutect2, varscan2
- NLGN1 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV64332044; called by muse, mutect2, varscan2
- NOTCH2 | c.2068C>T p.P690S | Missense Mutation (SNP) | VAF 327/528 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56680991; called by muse, mutect2, varscan2
- NPAS4 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV60650183; called by muse, mutect2, varscan2
- NPR1 | c.3103C>T p.R1035* | Nonsense Mutation (SNP) | VAF 36/117 reads (31%) | catalogued as COSV64117244; called by muse, mutect2, varscan2
- NPR3 | c.1265C>T p.T422I | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54087187; called by muse, mutect2, varscan2
- NT5DC3 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.028); catalogued as rs377569478; called by muse, mutect2, varscan2
- OR11A1 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65820916; called by muse, mutect2, varscan2
- OR1D2 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV58921452; called by muse, mutect2, varscan2
- OR1G1 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs950825015, COSV61029728, COSV61030128; called by muse, mutect2, varscan2
- OR1J2 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58944300; called by muse, mutect2, varscan2
- OR4M1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 87/267 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV60059274; called by muse, mutect2, varscan2
- OR4X1 | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60722524, COSV60722812; called by muse, mutect2
- OR5AC2 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV62279403; called by muse, mutect2, varscan2
- OR6A2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as COSV60264662; called by muse, mutect2, varscan2
- OR7E24 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.164); catalogued as COSV71702198, COSV71702234; called by muse, mutect2, varscan2
- PAK5 | c.1869+1G>A p.X623_splice | Splice Site (SNP) | VAF 77/155 reads (50%) | catalogued as COSV62026505; called by muse, mutect2, varscan2
- PCDHA5 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.453); catalogued as rs782270445, COSV65351910; called by muse, mutect2, varscan2
- PCYT1A | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV53057402; called by muse, mutect2, varscan2
- PDE8A | c.1330C>T p.L444F | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV59636729; called by muse, mutect2, varscan2
- PER3 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs145870917; called by muse, mutect2, varscan2
- PKD1L2 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as rs767889853, COSV100450192; called by muse, mutect2, varscan2
- PLCH2 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as rs765947066, COSV53942326; called by mutect2, varscan2
- PPA1 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 27/29 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV64683720; called by muse, mutect2, varscan2
- PRKD3 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.028); catalogued as COSV52213052; called by muse, mutect2, varscan2
- PRPF40A | c.2171G>A p.G724E | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV68357206; called by muse, mutect2, varscan2
- PTGS1 | c.997C>T p.L333F | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV56291571; called by muse, mutect2, varscan2
- PTPRD | c.5354G>A p.R1785K | Missense Mutation (SNP) | VAF 63/73 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100646018, COSV61942654; called by muse, mutect2, varscan2
- PTPRT | c.2810A>C p.D937A | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV61978465; called by muse, mutect2, varscan2
- PZP | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54359519; called by muse, mutect2, varscan2
- RAB3GAP1 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 95/207 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1432786831, COSV51481757; called by muse, mutect2, varscan2
- RBL2 | c.3097C>A p.P1033T | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50876594; called by muse, mutect2
- REG4 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 132/429 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749947655, COSV56653031; called by muse, varscan2
- RIF1 | c.320C>T p.T107I | Missense Mutation (SNP) | VAF 121/262 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54616516; called by muse, mutect2, varscan2
- RNF19A | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV61992647; called by muse, mutect2, varscan2
- RP1 | c.2543G>A p.R848K | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV55115836; called by muse, mutect2, varscan2
- RYR3 | c.9748A>C p.I3250L (on ENST00000389232; = p.I3251L on NM_001036.6) | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as rs1050830471, COSV66786775; called by muse, mutect2, varscan2
- SAMD9 | c.3155C>T p.S1052F | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs267601628, COSV66074857; called by muse, mutect2, varscan2
- SCG2 | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV59539835; called by muse, mutect2, varscan2
- SCRN3 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs867652339, COSV55807981; called by muse, mutect2, varscan2
- SF3B3 | c.848G>A p.R283K | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV56787272, COSV56787429; called by muse, mutect2, varscan2
- SLC22A9 | c.614T>C p.L205S | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1160837480, COSV54167045; called by muse, mutect2, varscan2
- SLC28A2 | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61663909; called by muse, mutect2, varscan2
- SLC35A5 | c.707T>C p.I236T | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as rs771349675, COSV53726679; called by muse, mutect2, varscan2
- SLC36A4 | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 194/434 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV58395979; called by muse, mutect2, varscan2
- SLC6A19 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.15); catalogued as COSV58670778; called by muse, mutect2, varscan2
- SORL1 | c.3475C>T p.R1159W | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs755000690, COSV52753838; called by muse, mutect2, varscan2
- SPEF2 | c.958A>C p.I320L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV56796335; called by muse, mutect2, varscan2
- SPIN1 | c.116G>T p.S39I | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV101020958, COSV65499229; called by muse, mutect2, varscan2
- SPOCD1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.203); catalogued as COSV57095999; called by muse, mutect2, varscan2
- STAB1 | c.3905C>T p.S1302F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.202); catalogued as COSV58734546, COSV58735550; called by muse, mutect2, varscan2
- STAT4 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as rs757999757, COSV61829516; called by muse, mutect2, varscan2
- SULT1E1 | c.496+1G>A p.X166_splice | Splice Site (SNP) | VAF 23/78 reads (29%) | catalogued as COSV56946911; called by muse, mutect2, varscan2
- SUSD4 | c.656C>A p.S219Y | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV59552302; called by mutect2, varscan2
- SYBU | c.278C>T p.P93L (on ENST00000276646 / NM_001099754.2; = p.P92L on NM_017786.6) | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52617389; called by muse, mutect2, varscan2
- SYCP2 | c.2530G>A p.E844K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV62767181; called by muse, mutect2, varscan2
- SYNDIG1 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370890052; called by muse, mutect2, varscan2
- TCERG1 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as rs1286361386; called by muse, mutect2, varscan2
- TESPA1 | c.797C>T p.S266F (on ENST00000316577 / NM_001098815.3; = p.S128F on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV57258657; called by muse, mutect2, varscan2
- TEX30 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs750616260, COSV65696395; called by muse, mutect2, varscan2
- TG | c.7867G>A p.E2623K | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV55074258; called by muse, mutect2, varscan2
- THADA | c.128T>G p.V43G | Missense Mutation (SNP) | VAF 174/415 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV67089804; called by muse, mutect2, varscan2
- TINF2 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 64/275 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV57468778; called by muse, varscan2
- TLCD4 | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV64632246; called by muse, mutect2, varscan2
- TMC1 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52774418; called by muse, mutect2, varscan2
- TMEM119 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.136); catalogued as COSV67188680; called by muse, mutect2, varscan2
- TMEM41B | c.411A>G p.I137M | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55155068; called by muse, mutect2, varscan2
- TNNC2 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV65332588; called by muse, mutect2, varscan2
- TNS4 | c.1908G>A p.R636= | Splice Region (SNP) | VAF 20/61 reads (33%) | catalogued as COSV54188527; called by muse, mutect2, varscan2
- TNS4 | c.1907G>A p.R636K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99563831; called by muse, mutect2, varscan2
- TOMM40 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV52977077; called by mutect2, varscan2
- TP53BP2 | c.1673G>A p.R558K (on ENST00000343537 / NM_001031685.3; = p.R429K on NM_005426.2) | Missense Mutation (SNP) | VAF 87/272 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.97); catalogued as COSV59068083; called by muse, mutect2, varscan2
- TRAF5 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV54822417; called by muse, mutect2, varscan2
- TRPS1 | c.1751C>T p.P584L (on ENST00000220888 / NM_001330599.2; = p.P597L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as rs762906317, COSV55235147; called by muse, mutect2, varscan2
- TTC6 | c.857G>A p.S286N (on ENST00000267368; = p.S1652N on NM_001310135.3) | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.109); catalogued as COSV57448575; called by muse, mutect2, varscan2
- TTLL12 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as rs143398079; called by muse, mutect2, varscan2
- UBE3B | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs754416261, COSV55093377; called by muse, mutect2, varscan2
- USP17L2 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs1405006019, COSV61555827; called by muse, varscan2
- VWF | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); catalogued as COSV54618847; called by muse, mutect2, varscan2
- ZBTB7C | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59688590; called by muse, mutect2, varscan2
- ZFP69B | c.1484G>A p.R495K | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.988); catalogued as COSV64315017, COSV64315368; called by muse, mutect2, varscan2
- ZIC2 | c.811A>C p.K271Q | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV66254929; called by muse, mutect2, varscan2
- ZIM2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55627978, COSV55629293; called by muse, mutect2, varscan2
- ZMYM2 | c.3405G>T p.E1135D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV67033813; called by mutect2, varscan2
- ZNF215 | c.1184T>C p.I395T | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.012); catalogued as COSV53492845; called by muse, mutect2, varscan2
- ZNF528 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.78); PolyPhen benign (0.067); catalogued as COSV64619170; called by muse, mutect2, varscan2
- ZNF600 | c.1784C>T p.S595L | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV57742458; called by muse, mutect2, varscan2
- ZNF750 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs766066825, COSV53960093; called by muse, mutect2, varscan2
- ZNF804B | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60825844; called by muse, mutect2, varscan2
- AKT1 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD109 | c.2152A>T p.T718S | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIA3 | c.2374G>A p.D792N | Missense Mutation (SNP) | VAF 47/52 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MORC1 | c.2065G>A p.G689R | Missense Mutation (SNP) | VAF 163/306 reads (53%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SRGAP2 | c.2059C>T p.P687S (on ENST00000624873 / NM_001170637.4; = p.P688S on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/199 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- SRP68 | c.1331del p.L444* | Frame Shift Del (DEL) | VAF 53/159 reads (33%) | called by mutect2, pindel, varscan2
- TCERG1 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRAJ12 | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 53/93 reads (57%) | PolyPhen benign (0.01); called by muse, mutect2, varscan2
- UBXN4 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UMODL1 | c.2091_2092insC p.T698Hfs*71 (on ENST00000408910 / NM_001004416.2; = p.T826Hfs*71 on NM_173568.3) | Frame Shift Ins (INS) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- ABCG2 | c.1080G>A p.K360= | Silent (SNP) | VAF 80/140 reads (57%) | catalogued as COSV52945659; called by muse, mutect2, varscan2
- ADAM20 | c.576C>T p.F192= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV56454877; called by muse, mutect2, varscan2
- ADRM1 | c.768C>T p.A256= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs754517311, COSV53358855; called by muse, mutect2, varscan2
- AKT1 | c.579C>T p.A193= | Silent (SNP) | VAF 21/37 reads (57%) | called by muse, mutect2, varscan2
- ANKRD11 | c.4716C>T p.L1572= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs760190551, COSV56360123; called by muse, mutect2, varscan2
- ATP6V1F | c.6G>C p.A2= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- ATXN7 | c.1323A>T p.V441= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV55750334; called by muse, mutect2, varscan2
- ATXN7L2 | c.1698G>A p.E566= | Silent (SNP) | VAF 219/404 reads (54%) | catalogued as COSV60204688; called by muse, mutect2, varscan2
- C2orf16 | c.4785G>A p.R1595= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as rs267599329, COSV62675267; called by muse, mutect2, varscan2
- C5AR2 | c.117C>T p.L39= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV57255938; called by muse, mutect2, varscan2
- CDH11 | c.1797G>T p.G599= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV51760258; called by mutect2, varscan2
- CENPM | c.489G>A p.L163= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV53245009; called by muse, mutect2, varscan2
- CNTN5 | c.3273G>A p.L1091= | Silent (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- COL6A6 | c.4623C>T p.P1541= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV62023974; called by muse, mutect2, varscan2
- DDX1 | c.36G>A p.E12= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV51839668; called by muse, mutect2, varscan2
- DGKZ | c.1245C>T p.I415= (on ENST00000454345 / NM_001105540.2; = p.I227= on NM_003646.4) | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs374806809; called by muse, mutect2, varscan2
- DYNC1H1 | c.2334C>T p.A778= | Silent (SNP) | VAF 49/86 reads (57%) | catalogued as rs957105344, COSV64136539; called by muse, mutect2, varscan2
- DYNC1LI1 | c.282G>A p.K94= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV56127423; called by muse, mutect2, varscan2
- EIF5B | c.1497G>A p.E499= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV56812662, COSV99178795; called by muse, mutect2, varscan2
- EPHA8 | c.2853C>T p.F951= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs955103893, COSV51267381; called by muse, mutect2, varscan2
- FAM83B | c.1200C>T p.L400= | Silent (SNP) | VAF 54/90 reads (60%) | catalogued as COSV60919789; called by muse, mutect2, varscan2
- FAM83B | c.1201C>T p.L401= | Silent (SNP) | VAF 53/89 reads (60%) | called by muse, mutect2, varscan2
- FMN2 | c.1818A>G p.Q606= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as COSV60417053, COSV60428554; called by muse, mutect2, varscan2
- FSD2 | c.960C>T p.F320= | Silent (SNP) | VAF 129/331 reads (39%) | catalogued as COSV58009754; called by muse, mutect2, varscan2
- GSDMB | c.792C>T p.V264= (on ENST00000418519 / NM_001165958.1; = p.V242= on NM_018530.2) | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV58780576; called by muse, mutect2, varscan2
- HELB | c.2823T>C p.F941= | Silent (SNP) | VAF 32/51 reads (63%) | catalogued as COSV56073601; called by muse, mutect2, varscan2
- HJURP | c.2091C>T p.S697= | Silent (SNP) | VAF 63/147 reads (43%) | catalogued as COSV64978744; called by muse, mutect2, varscan2
- HPF1 | c.951T>C p.Y317= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV66421885; called by muse, mutect2, varscan2
- ITIH4 | c.1224C>T p.G408= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV56573707, COSV56573999; called by muse, varscan2
- KCNH7 | c.1596C>T p.L532= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as COSV59795229, COSV59796958; called by muse, mutect2, varscan2
- KRT25 | c.1059C>T p.H353= | Silent (SNP) | VAF 100/220 reads (45%) | catalogued as COSV56444663; called by muse, mutect2, varscan2
- KRT4 | c.69C>T p.G23= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs765838470, COSV53407123; called by muse, mutect2, varscan2
- KRTAP21-1 | c.147T>C p.G49= | Silent (SNP) | VAF 59/143 reads (41%) | catalogued as COSV58646388; called by muse, mutect2, varscan2
- LRP2 | c.10518C>T p.T3506= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV55551422; called by muse, mutect2, varscan2
- MROH2B | c.4452G>A p.R1484= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV68183509; called by muse, mutect2, varscan2
- MYL9 | c.351C>T p.F117= | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as COSV54072215, COSV54072376; called by muse, mutect2, varscan2
- MYLK | c.4329G>A p.K1443= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as COSV60609468; called by muse, mutect2, varscan2
- NIBAN2 | c.1470G>A p.R490= | Silent (SNP) | VAF 35/65 reads (54%) | catalogued as COSV55939838; called by muse, mutect2, varscan2
- NIBAN3 | c.597C>T p.F199= | Silent (SNP) | VAF 53/129 reads (41%) | catalogued as rs376855441, COSV56308596; called by muse, mutect2, varscan2
- NLRP12 | c.2043C>T p.S681= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs141711127; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOTCH2 | c.6930C>T p.I2310= | Silent (SNP) | VAF 126/444 reads (28%) | catalogued as COSV56690401; called by muse, mutect2, varscan2
- NRROS | c.90C>T p.S30= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV60745679; called by muse, mutect2, varscan2
- NUAK1 | c.1410G>A p.K470= | Silent (SNP) | VAF 27/45 reads (60%) | catalogued as rs751534999, COSV54601714; called by muse, varscan2
- NXNL1 | c.301C>T p.L101= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as COSV57324710; called by muse, mutect2, varscan2
- OAS3 | c.1749C>T p.F583= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs756617468, COSV57445440; called by mutect2, varscan2
- OBSCN | c.10266G>T p.L3422= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV52770024; called by muse, mutect2, varscan2
- OR10J5 | c.93C>T p.F31= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs748213019, COSV58384961; called by muse, mutect2, varscan2
- OR13C2 | c.201C>T p.S67= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs922767934; called by muse, mutect2, varscan2
- OR14K1 | c.276C>T p.F92= | Silent (SNP) | VAF 40/60 reads (67%) | catalogued as COSV51720311; called by muse, mutect2, varscan2
- OR1D2 | c.309C>T p.F103= | Silent (SNP) | VAF 87/172 reads (51%) | catalogued as COSV58921543; called by muse, mutect2, varscan2
- PKD1 | c.12507C>T p.S4169= (on ENST00000262304 / NM_001009944.3; = p.S4168= on NM_000296.4) | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs780509938, COSV51915181; called by muse, mutect2, varscan2
- PKD1L2 | c.372C>T p.A124= | Silent (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- PLCE1 | c.4290G>A p.L1430= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV53346812, COSV53355726; called by mutect2, varscan2
- POLR1B | c.1764A>G p.R588= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV54497502; called by muse, mutect2, varscan2
- PRAMEF4 | c.1173C>T p.P391= | Silent (SNP) | VAF 147/278 reads (53%) | catalogued as COSV52438442; called by muse, mutect2, varscan2
- PRPF40B | c.1842G>A p.R614= (on ENST00000380281; = p.R601= on NM_012272.3) | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV53301328; called by muse, mutect2, varscan2
- RAD23A | c.891G>T p.V297= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV57535436; called by muse, mutect2, varscan2
- RB1CC1 | c.3255G>A p.Q1085= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV50244435, COSV50270164; called by muse, mutect2, varscan2
- REV1 | c.453G>A p.E151= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs1189097304, COSV51484625; called by muse, mutect2, varscan2
- RGS12 | c.462G>A p.P154= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs774176669, COSV60904434; called by mutect2, varscan2
- RPH3AL | c.57G>A p.R19= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV58741833; called by muse, mutect2, varscan2
- RPS6KA1 | c.192C>T p.L64= | Silent (SNP) | VAF 32/52 reads (62%) | catalogued as rs370115968; called by muse, mutect2, varscan2
- SEC14L4 | c.1206C>T p.P402= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs1166285777, COSV55399534, COSV99742893; called by muse, mutect2, varscan2
- SERINC4 | c.1299C>T p.F433= | Silent (SNP) | VAF 54/114 reads (47%) | catalogued as COSV51049125; called by muse, mutect2, varscan2
- SERPINF1 | c.291G>A p.E97= | Silent (SNP) | VAF 66/148 reads (45%) | catalogued as COSV54616156; called by muse, mutect2, varscan2
- SETBP1 | c.1647C>T p.A549= | Silent (SNP) | VAF 54/169 reads (32%) | catalogued as COSV56320571; called by muse, mutect2, varscan2
- SETBP1 | c.3987C>T p.S1329= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs1489343617; called by muse, varscan2
- SH3BP4 | c.2475G>A p.V825= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV60643743; called by muse, varscan2
- SLC30A5 | c.1254G>A p.Q418= | Silent (SNP) | VAF 44/60 reads (73%) | catalogued as COSV67449393; called by muse, mutect2, varscan2
- SLC35A2 | c.975C>T p.A325= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV54430278; called by muse, mutect2
- SLITRK6 | c.1644C>T p.S548= | Silent (SNP) | VAF 38/62 reads (61%) | catalogued as COSV101233284, COSV68390062; called by muse, mutect2, varscan2
- SRGAP2 | c.2058C>T p.G686= (on ENST00000624873 / NM_001170637.4; = p.G687= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 100/200 reads (50%) | called by muse, mutect2, varscan2
- TACC2 | c.8259C>T p.I2753= (on ENST00000334433; = p.I831= on NM_006997.4) | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as rs1268666853, COSV53280506; called by muse, mutect2, varscan2
- TAS2R5 | c.144C>T p.I48= | Silent (SNP) | VAF 76/82 reads (93%) | catalogued as COSV56094419; called by muse, mutect2, varscan2
- TFAP4 | c.744C>T p.I248= | Silent (SNP) | VAF 48/79 reads (61%) | catalogued as COSV52597472; called by muse, mutect2, varscan2
- TPTE | c.345C>T p.F115= (on ENST00000618007 / NM_199261.4; = p.F97= on NM_199259.4) | Silent (SNP) | VAF 57/194 reads (29%) | called by muse, mutect2, varscan2
- TRIOBP | c.1824C>T p.P608= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV60376824; called by muse, varscan2
- TTN | c.44715G>A p.K14905= (on ENST00000591111; = p.K7481= on NM_003319.4) | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs7355450, COSV60022923, COSV60142126; called by muse, mutect2, varscan2
- USPL1 | c.2703G>A p.K901= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV54999805, COSV55001029; called by muse, mutect2, varscan2
- VCAN | c.8916A>C p.T2972= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as COSV54104027; called by muse, mutect2, varscan2
- VSIG8 | c.516C>T p.G172= | Silent (SNP) | VAF 45/62 reads (73%) | catalogued as rs750153493, COSV63652812; called by muse, mutect2, varscan2
- WDR62 | c.3396C>T p.G1132= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs765013257, COSV54334528; called by mutect2, varscan2
- WDR93 | c.1623C>T p.S541= | Silent (SNP) | VAF 72/151 reads (48%) | catalogued as COSV51531798; called by muse, mutect2, varscan2
- WNK2 | c.4797G>A p.Q1599= (on ENST00000297954 / NM_001282394.1; = p.Q1562= on NM_006648.3) | Silent (SNP) | VAF 26/38 reads (68%) | catalogued as COSV52940220; called by muse, mutect2, varscan2
- ZNF91 | c.3486C>T p.I1162= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV56084008; called by muse, mutect2, varscan2
- ZSWIM5 | c.1749G>A p.Q583= | Silent (SNP) | VAF 48/87 reads (55%) | catalogued as COSV62734052; called by muse, varscan2
- AL353804.7 | chrX:73851834 C>T | 3'Flank (SNP) | VAF 52/62 reads (84%) | called by muse, mutect2, varscan2
- AMFR | c.*162C>T | 3'UTR (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99315806; called by mutect2, varscan2
- DDX41 | c.*234C>G | 3'UTR (SNP) | VAF 9/68 reads (13%) | catalogued as rs556677138, COSV57251816, COSV57252040; called by muse, mutect2, varscan2
- DIDO1 | c.1588+61C>T | Intron (SNP) | VAF 48/104 reads (46%) | called by muse, mutect2, varscan2
- EIF4A2 | c.771+54A>G | Intron (SNP) | VAF 21/70 reads (30%) | catalogued as COSV99961151; called by muse, mutect2, varscan2
- MIR409 | n.44G>A | RNA (SNP) | VAF 24/53 reads (45%) | catalogued as rs749590166; called by muse, mutect2, varscan2
- NACA | c.71-2518C>T | Intron (SNP) | VAF 19/32 reads (59%) | catalogued as rs574552110; called by muse, mutect2, varscan2
- PRR12 | c.51+418C>T | Intron (SNP) | VAF 42/77 reads (55%) | catalogued as COSV55870124; called by muse, mutect2, varscan2
- SNORD115-33 | n.67G>A | RNA (SNP) | VAF 77/205 reads (38%) | called by muse, mutect2, varscan2
- TTN | c.10361-5323C>T | Intron (SNP) | VAF 21/55 reads (38%) | catalogued as COSV60185746; called by muse, mutect2, varscan2
